Somatic mutation profile of tumor specimen TARGET-15-SJMPAL041118-09A.1 (aliquot TARGET-15-SJMPAL041118-09A.1-01D) from TARGET case TARGET-15-SJMPAL041118, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.0 years (3,295 days).
Specimen TARGET-15-SJMPAL041118-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5321774-b414-484a-8870-b5e48f8094ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL041118-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL041118-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ef2ab98-5652-4f67-a1de-894ac9af0607

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 2, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104894364, CM061079, COSV55527371, COSV99800760; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 50/270 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- F12 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as rs757778469; called by mutect2, varscan2
- GALNT9 | c.800G>A p.R267H | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs556119200; called by muse, varscan2
- GLUD1 | c.187G>T p.D63Y | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53280422; called by muse, mutect2, varscan2
- BAZ2B | c.631A>C p.K211Q | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- MUC17 | c.1270G>A p.V424M | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- NTNG1 | c.809C>A p.A270D | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHGA7 | c.724T>A p.F242I | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- SETD2 | c.5278_5290delinsCGGA p.N1760_Q1764delinsRK | Splice Region (DEL) | VAF 14/78 reads (18%) | called by pindel, varscan2*
- ADCY10 | c.3435C>T p.G1145= | Silent (SNP) | VAF 27/133 reads (20%) | called by muse, mutect2, varscan2
- RNF40 | c.1147C>A p.R383= | Silent (SNP) | VAF 4/35 reads (11%) | catalogued as COSV61215283; called by mutect2, varscan2
- ZFHX4 | c.8703G>A p.T2901= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs1192176251, COSV51480253; called by muse, mutect2, varscan2
- ASIC4 | c.-216C>A | 5'UTR (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2
- CNOT1 | c.4434+122G>T | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- JPH3 | c.2167-1080C>G | Intron (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
